Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A7VC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A7VC-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Left axillary Sentinel lymph node: One lymph node, no evidence of metastatic carcinoma. Confirmed by negative staining for pancytokeratin.

B. Left breast mastectomy:

Metaplastic carcinoma with areas of chondroid differentiation..

Size: 11 cm.

Architectural score: 3 of 3.

Nuclear score: 3 of 3.

Mitotic score: 3 of 3.

Total score: 9 of 9.

Grade 3.

No evidence of in situ carcinoma.

No evidence of angiolymphatic invasion.

Prognostic panel to follow.

All surgical margins of excision are free of carcinoma.

No evidence of skin or nipple involvement.

TMN: T3pN0(-)

ICD-O-3

Carcinoma, metaplastic NOS
8575/3

Site 4 Breast NOS
C50.9

HW 10/2/13

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Left breast mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Left axillary sentinel lymph nodes

B. Left breast - short stitch superior

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is labeled
submitted in cassettes A1-A2 labeled

Received in formalin, is a 3.0 x 1.3 x 0.8 cm slightly blue-dyed tan lymph node. The specimen is sectioned and

B. Container B is labeled

left breast. Received in formalin, is a 1,044 gram, 23.0 x 17.5 x 5.0 cm left simple mastectomy surfaced on one aspect by a 20.0 x 11.2 cm ellipse of tan-white skin with a low-central 1.2 x 1.2 x 0.3 cm nipple which exudes no discharge. Surrounding the nipple, there is a 6.0 cm diameter patch of intense blue-dyed discoloration. The specimen is oriented with a suture at the mid aspect of one long axis indicating superior. The deep aspect of the specimen has been previously sectioned for collection of tissue for genomics studies. At the previous incision site, the cut surfaces give rise to a subareolar, 11.0 x 10.0 x 8.0 cm indurated, well circumscribed, focally cystic and mucinous tumor. The tumor is 3.5 cm from the nearest deep margin and 3.2 cm from the nearest skin resection margin. The remaining breast parenchyma is 20% fibrous tissue. There are no lymph nodes near the upper outer quadrant.

Sections are submitted in two cassettes for genomics studies labeled

are submitted in cassettes labeled

as follows: B1 representative nipple; B2-B7 representative tumor; B8-B9 representative uninvolved upper outer quadrant; B10-B11 representative of upper inner quadrant; B12-B13 representative of lower inner quadrant; B14-B15 representative of lower outer quadrant.

[page 2 of 2]
The left breast mass consists of a malignant neoplasm composed predominantly of spindle cells. There are areas of chondroid differentiation and areas of multinucleated tumor giant cells. A broad panel cytokeratins was utilized. The tumor cells were negative for high molecular weight keratin SK. There is focal positivity for cytokeratin AE 1,3. Rare tumor cells are positive for pancytokeratin. Rare tumor cells are positive for cytokeratin cam 5.2. They are negative for cytokeratin CKC 7 and CK 20. There is strong positivity for P 63. This is indicative of a metaplastic carcinoma.

Staging Discrepancy		☒
Discrepancy Primary Method		☒

Source: NCI Genomic Data Commons file e1129743-70fb-4466-9710-2b9beff4457b (TCGA-AC-A7VC.A1681334-684E-41E0-B3FA-EFFE1E5A8B7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).